Somatic mutation profile of tumor specimen MMRF_1854_3_BM_CD138pos (aliquot MMRF_1854_3_BM_CD138pos_T1_KHS5U_L08854) from MMRF case MMRF_1854, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.9 years (19,326 days).
Specimen MMRF_1854_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aa1fb8b-c75a-45a6-a8e7-7be94e592409.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1854_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1854_1_PB_Whole_C3_KBS5U_L05574; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4143e82-9ff9-49c5-a238-1bf9fe01e424

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHB2 | c.212+283_212+288del | Intron (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- SHTN1 | c.*3900_*3928delinsGCAATTCAGGCAATGGATATGTCACATC | 3'UTR (DEL) | VAF 5/57 reads (9%) | called by pindel, varscan2*
